Somatic mutation profile of tumor specimen BA2945D (aliquot aq-BA2945D) from BEATAML1.0 case 2311, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.1 years (23,421 days).
Specimen BA2945D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 509926f2-07e9-49d7-a800-5ede08cce7cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2711D (Solid Tissue Normal), aliquot aq-BA2711D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba28fe4c-49bc-4244-9ba1-c5afa0874046

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 4, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.2494G>T p.G832C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61249651; called by muse, mutect2
- GLP1R | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.58); catalogued as rs1242484640, COSV64716502; called by muse, mutect2, varscan2
- WDR33 | c.3698G>T p.R1233L | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV59246604, COSV59250938; called by muse, mutect2
- ALPG | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2
- BTBD8 | c.4766A>G p.H1589R (on ENST00000636805 / NM_001376131.1; = p.H1076R on NM_015237.4) | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ESRP1 | c.91_92insAA p.I31Kfs*23 | Frame Shift Ins (INS) | VAF 11/90 reads (12%) | called by mutect2, pindel, varscan2
- MYH6 | c.3013C>T p.H1005Y | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.379); called by muse, mutect2
- KRT80 | c.288C>T p.S96= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- TICRR | c.3786G>A p.Q1262= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as rs950570288; called by muse, mutect2
- TRPM1 | c.1650T>A p.T550= | Silent (SNP) | VAF 15/381 reads (4%) | called by muse, mutect2
- ACY1 | c.1002-16G>T | Intron (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
- OLFM1 | c.457-490G>A | Intron (SNP) | VAF 11/243 reads (5%) | called by muse, mutect2
- TMEM70 | c.316+265C>A | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- UNC45A | c.2073+16C>A | Intron (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
